Somatic mutation profile of tumor specimen TCGA-V5-AASW-01A (aliquot TCGA-V5-AASW-01A-11D-A403-09) from TCGA case TCGA-V5-AASW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3; Age at diagnosis: 72.7 years (26,571 days).
Specimen TCGA-V5-AASW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ce99209-98bd-40bf-8db7-395b2233e21a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V5-AASW-10A (Blood Derived Normal), aliquot TCGA-V5-AASW-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5814314-67a8-434a-a138-51f7892ff863

The open-access MAF lists 136 somatic variants for this specimen: 89 protein-altering or splice-affecting, 43 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 43, Intron 4, Frame Shift Ins 3, Nonsense Mutation 3, In Frame Del 1, In Frame Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NR1D2 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358487339, CM164975, COSV56993276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 18/24 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC024598.1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as rs371278525, COSV60824183; called by muse, mutect2, varscan2
- ACTN2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.833); catalogued as rs758358941, COSV63973008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD50 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs747807273, COSV72385123, COSV72385938; called by muse, mutect2, varscan2
- ATP10D | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765924864, COSV56715772; called by muse, mutect2, varscan2
- BCL11A | c.1129G>A p.D377N (on ENST00000335712 / NM_001365609.1; = p.D411N on NM_018014.4) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100186751; called by muse, mutect2, varscan2
- BRINP2 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763172017, COSV64175944; called by muse, mutect2, varscan2
- CDK5RAP1 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV59427218; called by muse, mutect2, varscan2
- COL18A1 | c.2005G>A p.G669R (on ENST00000359759 / NM_130444.3; = p.G434R on NM_030582.4) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766459944; called by muse, mutect2, varscan2
- DOCK11 | c.4115G>A p.S1372N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.765); catalogued as COSV52233461; called by muse, mutect2, varscan2
- DTX2 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs1208427242; called by mutect2, varscan2
- EGFL7 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as rs372445708; called by muse, mutect2, varscan2
- EPC1 | c.2314A>G p.I772V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1185190060; called by muse, mutect2, varscan2
- ETV1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.609); catalogued as COSV54143755; called by muse, mutect2, varscan2
- FAM135B | c.1303A>C p.S435R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV52713366; called by muse, mutect2, varscan2
- GPR52 | c.42G>T p.M14I | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV52302069; called by muse, mutect2, varscan2
- GRIA4 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56882865; called by muse, mutect2, varscan2
- IFI44L | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770941163; called by muse, mutect2, varscan2
- KCNH1 | c.1408G>A p.A470T (on ENST00000271751 / NM_172362.3; = p.A443T on NM_002238.4) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV55094358, COSV99657601; called by muse, mutect2, varscan2
- KIR2DL3 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as rs746107872, COSV100668026; called by muse, mutect2
- KIRREL2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1439192947; called by muse, mutect2
- MINK1 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs1486725022; called by muse, mutect2, varscan2
- MROH5 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285296199, COSV101435881; called by muse, mutect2, varscan2
- MYBL1 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs373484712; called by muse, mutect2, varscan2
- OR10A5 | c.661C>G p.R221G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as COSV100203376; called by muse, mutect2, varscan2
- OR6C76 | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.604); catalogued as rs968391448; called by muse, mutect2, varscan2
- OS9 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs369079310; called by muse, mutect2, varscan2
- PROSER3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV56554465; called by muse, mutect2, varscan2
- R3HCC1L | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as rs1234635384; called by muse, mutect2, varscan2
- RASSF7 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1424846889; called by muse, mutect2, varscan2
- SIAE | c.1296G>C p.Q432H | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99422405; called by muse, mutect2
- SIGLEC1 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs558364870; called by muse, mutect2, varscan2
- SIPA1L1 | c.5233G>A p.E1745K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs756320976; called by muse, mutect2, varscan2
- SNX10 | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV58402788; called by muse, mutect2, varscan2
- STAB2 | c.5551G>A p.G1851S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs759682784; called by muse, mutect2, varscan2
- TASOR | c.1729C>T p.P577S (on ENST00000355628 / NM_001365636.2; = p.P181S on NM_015224.3) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1293289558; called by muse, mutect2, varscan2
- TBC1D4 | c.1370C>G p.P457R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66487991, COSV66489513; called by muse, mutect2, varscan2
- TENM1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.642); catalogued as COSV100948774; called by muse, mutect2
- TPST2 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs747594236; called by muse, mutect2, varscan2
- TRPM3 | c.4938G>T p.E1646D (on ENST00000357533 / NM_001366142.2; = p.E1501D on NM_020952.6) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV62591828; called by muse, mutect2, varscan2
- UBR1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV51928614; called by muse, mutect2, varscan2
- VWA8 | c.5281G>A p.V1761I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.094); catalogued as rs778640647; called by muse, mutect2, varscan2
- AFF2 | c.2995A>G p.T999A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ATP10D | c.3169G>A p.G1057S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CATSPERG | c.3402G>A p.M1134I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- CCDC34 | c.722A>G p.K241R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CSNK1A1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIDO1 | c.5968G>T p.G1990C | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DNAJC13 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EGFL7 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EP400 | c.9106C>T p.P3036S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESR1 | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ESRRG | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FAM78B | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FBXL20 | c.1125G>C p.L375F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GOLM2 | c.446A>T p.K149M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HDGF | c.479A>T p.D160V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- HELZ | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- HLX | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRF2BP2 | c.896_897dup p.N300Sfs*33 | Frame Shift Ins (INS) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.2230G>A p.V744I | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIR3DL3 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- KMT2E | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- LRRC7 | c.4351C>T p.P1451S (on ENST00000651989 / NM_001370785.2; = p.P1371S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MAML2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- MTA2 | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUP153 | c.2975C>A p.P992Q | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NXPE3 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- PHKA1 | c.1714+1G>C p.X572_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1372_1377dup p.E458_K459dup (on ENST00000521381 / NM_181523.3; = p.E188_K189dup on NM_181504.4) | In Frame Ins (INS) | VAF 32/62 reads (52%) | called by mutect2, varscan2
- PRRX2 | c.447G>A p.Q149= | Splice Region (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- PRSS12 | c.2611dup p.S871Kfs*75 | Frame Shift Ins (INS) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- RIMKLB | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- RNF150 | c.251A>G p.Q84R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHOC2 | c.1524C>A p.H508Q | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC11 | c.1758C>G p.I586M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SYNE1 | c.9247G>A p.A3083T (on ENST00000367255 / NM_182961.4; = p.A3090T on NM_033071.3) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SYNE1 | c.4745G>A p.C1582Y (on ENST00000367255 / NM_182961.4; = p.C1589Y on NM_033071.3) | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TCF12 | c.1005_1006insCT p.G336Lfs*70 | Frame Shift Ins (INS) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- TNFSF10 | c.541T>A p.F181I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UMODL1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- UNC13C | c.1650A>T p.E550D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UNC13C | c.1651T>A p.S551T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WNT2B | c.249_263del p.Q84_R88del (on ENST00000369684 / NM_024494.3; = p.Q65_R69del on NM_004185.4) | In Frame Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- ZBTB7B | c.785C>T p.S262F (on ENST00000292176; = p.S296F on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ZC3H13 | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- ZNF492 | c.1580G>C p.C527S | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZYX | c.782C>G p.A261G | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADCY1 | c.2856G>A p.A952= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs748141521, COSV52031850; called by muse, mutect2
- AFF3 | c.384T>C p.T128= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100418312; called by muse, mutect2
- ATP8B4 | c.2523C>A p.V841= | Silent (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- BLOC1S5 | c.546G>A p.A182= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs753376697; called by muse, mutect2, varscan2
- CD86 | c.864G>A p.E288= (on ENST00000330540 / NM_175862.5; = p.E282= on NM_006889.4) | Silent (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- CELF2 | c.1041C>T p.A347= (on ENST00000416382 / NM_001025077.3; = p.A354= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs895122765; called by muse, mutect2
- CGN | c.495C>T p.S165= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.894G>A p.T298= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs762840470, COSV70513678; called by mutect2, varscan2
- EDN3 | c.702G>A p.Q234= (on ENST00000337938 / NM_001302455.2; = p.Q220= on NM_207033.3) | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- FAM168A | c.339G>A p.P113= (on ENST00000064778 / NM_001286050.2; = p.P104= on NM_015159.3) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs769542145; called by muse, mutect2, varscan2
- FAM83C | c.1089C>T p.L363= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1027214353; called by muse, mutect2, varscan2
- GATA2 | c.1368G>A p.P456= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs569990126; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLB1L3 | c.234C>T p.P78= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- GPR35 | c.516C>T p.S172= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs763297051; called by muse, mutect2, varscan2
- IL22RA2 | c.447G>A p.T149= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as rs143485398; called by muse, mutect2, varscan2
- KCNJ2 | c.615C>T p.D205= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs767844416, COSV54660577, COSV54660999, COSV54662110; called by muse, varscan2
- KMT2D | c.1104G>A p.V368= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- LAMC3 | c.1995G>A p.P665= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs747496537, COSV63092152; called by muse, varscan2
- MBD5 | c.3754A>C p.R1252= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- MTF2 | c.91C>T p.L31= | Silent (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- MYO18B | c.888G>A p.G296= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- NFASC | c.813C>T p.S271= (on ENST00000339876 / NM_001378329.1; = p.S282= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs140997318; called by muse, mutect2
- NLRC3 | c.2271G>T p.L757= | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- NPR3 | c.852C>T p.Y284= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs374205048; called by muse, mutect2, varscan2
- OR10J5 | c.319T>C p.L107= | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- OR52L1 | c.912G>A p.A304= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs780095253, COSV59985658; called by muse, mutect2, varscan2
- PKLR | c.345G>A p.A115= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV61361767; called by muse, mutect2, varscan2
- POMK | c.192G>A p.Q64= | Silent (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- PXMP4 | c.579C>T p.S193= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- RCAN1 | c.444C>T p.S148= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- RMDN2 | c.543C>T p.V181= (on ENST00000354545 / NM_001322212.2; = p.V359= on NM_144713.5) | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- RP1 | c.2541G>A p.L847= | Silent (SNP) | VAF 53/76 reads (70%) | catalogued as COSV55120233; called by muse, mutect2, varscan2
- SAMSN1 | c.516G>A p.T172= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs745867626, COSV53467189; called by muse, mutect2, varscan2
- SHC3 | c.1392C>T p.P464= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV65439661; called by muse, mutect2, varscan2
- SLC2A1 | c.405G>C p.L135= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- SMC1B | c.3474A>G p.L1158= | Silent (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- SPEF2 | c.4245C>A p.R1415= | Silent (SNP) | VAF 47/61 reads (77%) | called by muse, mutect2, varscan2
- SPHKAP | c.2238G>A p.E746= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- SPTBN5 | c.3807A>G p.A1269= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- THAP4 | c.393G>C p.S131= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs191058185, COSV101126111; called by muse, mutect2, varscan2
- TTN | c.1449C>T p.A483= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as rs141617218; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- UXS1 | c.1137G>A p.P379= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs768124349; called by muse, mutect2, varscan2
- ZC3H12C | c.2133G>T p.P711= | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- CADPS | c.2582-892C>A | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- COL5A1 | c.654+7370G>A | Intron (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- PDZRN4 | c.844-28554G>C | Intron (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- RAC2 | c.107+562C>T | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
